Somatic mutation profile of tumor specimen TCGA-BR-6563-01A (aliquot TCGA-BR-6563-01A-13D-2053-08) from TCGA case TCGA-BR-6563, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 60.1 years (21,936 days).
Specimen TCGA-BR-6563-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0124b173-945f-4916-ba17-2cee5406bbc1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-6563-10A (Blood Derived Normal), aliquot TCGA-BR-6563-10A-01D-2053-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c51afe21-9095-47d2-8e7a-38588a2d712f

The open-access MAF lists 59 somatic variants for this specimen: 48 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 9, Nonsense Mutation 2, In Frame Del 1, 3'UTR 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RHOA | c.169T>G p.L57V | Missense Mutation (SNP) | VAF 12/98 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV69041945; called by muse, mutect2, varscan2
- TENT5D | c.205A>C p.S69R | Missense Mutation (SNP) | VAF 18/76 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57634984, COSV57635195, COSV57638952; called by muse, mutect2, varscan2
- ACAD10 | c.225A>G p.I75M | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as COSV58159390; called by muse, mutect2, varscan2
- ADGRG2 | c.461G>T p.S154I (on ENST00000379869 / NM_001079858.3; = p.S151I on NM_005756.4) | Missense Mutation (SNP) | VAF 41/173 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.14); catalogued as COSV61340122; called by muse, mutect2, varscan2
- ADRA2C | c.1225C>T p.R409C | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as COSV57467719; called by muse, mutect2
- APC | c.3314G>A p.R1105Q | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs548176472, COSV57359620; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAMK1D | c.838G>C p.A280P | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as COSV66609732, COSV66615386; called by muse, mutect2
- CC2D1A | c.1529G>A p.R510Q | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.74); PolyPhen benign (0.042); catalogued as rs867408303, COSV58784708; called by muse, mutect2
- CDH4 | c.1901C>T p.T634M | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779693148, COSV64663178; called by muse, mutect2, varscan2
- CHEK2 | c.590A>G p.N197S (on ENST00000382580 / NM_001005735.2; = p.N154S on NM_007194.4) | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.161); catalogued as COSV60422734; called by muse, mutect2, varscan2
- COL20A1 | c.2369C>T p.P790L | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as COSV58921548; called by muse, mutect2, varscan2
- CYSLTR1 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV64820655; called by muse, mutect2, varscan2
- DLGAP2 | c.1124C>T p.T375M | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs767514905, COSV70100262; called by muse, mutect2
- DMXL1 | c.7653T>A p.Y2551* | Nonsense Mutation (SNP) | VAF 18/152 reads (12%) | catalogued as COSV60716138; called by muse, mutect2, varscan2
- EPHA7 | c.2561G>A p.R854H | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs776802108, COSV65181235; called by muse, mutect2, varscan2
- ERBB3 | c.2012T>A p.I671N | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV57257879; called by muse, mutect2, varscan2
- EXOSC1 | c.546C>G p.F182L | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV58355858; called by muse, mutect2
- FAT4 | c.14223A>C p.Q4741H | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as COSV58695923; called by muse, mutect2
- FGD1 | c.2647C>T p.R883W | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.159); catalogued as rs1295137376, COSV64309122; called by muse, mutect2
- FLG | c.11582C>T p.S3861F | Missense Mutation (SNP) | VAF 20/312 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs762274526, COSV64244543; called by muse, mutect2
- FLG | c.3662G>A p.R1221H | Missense Mutation (SNP) | VAF 55/443 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs202164130, COSV64244547; called by muse, mutect2, varscan2
- GABRA3 | c.1379G>T p.R460L | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV64796181, COSV64805725; called by muse, mutect2, varscan2
- HEATR5B | c.1688T>A p.M563K | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV51855348; called by muse, mutect2, varscan2
- KANSL1 | c.2841C>A p.Y947* (on ENST00000574590 / NM_001193465.2; = p.Y948* on NM_015443.4) | Nonsense Mutation (SNP) | VAF 8/153 reads (5%) | catalogued as COSV99290239; called by muse, mutect2
- KATNAL2 | c.265A>G p.I89V (on ENST00000356157 / NM_001353899.1; = p.I17V on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs1175033693, COSV55302772, COSV55303367; called by muse, mutect2
- KLHL1 | c.1693A>G p.S565G | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV64776145; called by muse, mutect2
- KRT25 | c.1295G>A p.R432H | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs189090611, COSV56445657; called by muse, mutect2
- MUC16 | c.15695A>C p.K5232T | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.014); catalogued as COSV67478416; called by muse, mutect2
- MYO3A | c.74A>C p.E25A | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56335395, COSV56338667; called by muse, mutect2, varscan2
- NEXMIF | c.4379A>C p.E1460A | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50021655, COSV50051299; called by muse, mutect2
- NINL | c.2722C>T p.R908C | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1358052026, COSV54005267; called by muse, mutect2, varscan2
- OBSCN | c.58G>A p.V20M | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.094); catalogued as COSV52796047; called by muse, mutect2
- OR10A4 | c.872A>G p.Y291C | Missense Mutation (SNP) | VAF 13/163 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65842208; called by muse, mutect2
- PRPF8 | c.5665C>T p.L1889F | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV59265171; called by muse, mutect2
- RALGAPA1 | c.3322T>G p.S1108A | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV51888929; called by muse, mutect2
- RBM7 | c.308A>G p.H103R | Missense Mutation (SNP) | VAF 19/178 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV57784612; called by muse, mutect2, varscan2
- RBMS3 | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 26/201 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs376210051; called by muse, mutect2, varscan2
- SDR9C7 | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as rs141626978; called by muse, mutect2, varscan2
- SLITRK4 | c.1919T>A p.V640D | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV62025027; called by muse, mutect2, varscan2
- ST3GAL2 | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 24/234 reads (10%) | PolyPhen probably damaging (0.997); catalogued as COSV61595613; called by muse, mutect2
- SURF6 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.526); catalogued as rs782674966, COSV64395635; called by muse, mutect2
- SYNJ2 | c.3767T>G p.F1256C | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV62898793; called by muse, mutect2
- USP9X | c.3279+2T>C p.X1093_splice | Splice Site (SNP) | VAF 12/65 reads (18%) | catalogued as COSV61071788; called by muse, mutect2, varscan2
- ZNF208 | c.2807A>T p.K936M | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV101237161, COSV68101234, COSV68109514; called by mutect2, varscan2
- ZNF600 | c.1973G>T p.R658I | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.566); catalogued as COSV100593133, COSV57741329; called by muse, mutect2
- ZNF605 | c.1889C>T p.S630L | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs1219650083, COSV59159770; called by muse, mutect2, varscan2
- ZNF710 | c.832G>A p.V278M | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV51564292; called by muse, mutect2
- TGFBR2 | c.871_873del p.K291del | In Frame Del (DEL) | VAF 11/114 reads (10%) | called by mutect2, pindel
- ANKEF1 | c.426C>T p.V142= | Silent (SNP) | VAF 12/131 reads (9%) | catalogued as COSV65692828; called by muse, mutect2
- EYS | c.783A>G p.Q261= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV60988528, COSV60992461; called by muse, mutect2, varscan2
- FCGR3B | c.231C>T p.D77= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as rs375541897; called by muse, mutect2, varscan2
- GPR21 | c.579G>A p.L193= | Silent (SNP) | VAF 11/166 reads (7%) | catalogued as COSV65378787, COSV65379095; called by muse, mutect2
- LOXL1 | c.1383C>T p.Y461= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as rs748019800, COSV56094560; called by muse, mutect2
- NLRP4 | c.876G>T p.T292= | Silent (SNP) | VAF 9/104 reads (9%) | catalogued as COSV100016064; called by muse, mutect2
- POU3F4 | c.705C>T p.F235= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV64540054; called by muse, mutect2, varscan2
- RIN3 | c.789G>A p.P263= | Silent (SNP) | VAF 12/125 reads (10%) | catalogued as rs201235572, COSV53651808; called by muse, mutect2, varscan2
- WDR27 | c.504C>T p.R168= | Silent (SNP) | VAF 11/90 reads (12%) | catalogued as COSV61211652; called by muse, mutect2, varscan2
- CPLANE1 | c.*2476C>T | 3'UTR (SNP) | VAF 11/138 reads (8%) | catalogued as COSV57066451; called by muse, mutect2
- POLR2F | c.453-15195G>A | Intron (SNP) | VAF 5/42 reads (12%) | catalogued as rs1397340055; called by muse, mutect2
